Gene-level copy-number profile of tumor specimen TCGA-V5-A7RB-01A from TCGA case TCGA-V5-A7RB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 59.3 years (21,654 days).
Specimen TCGA-V5-A7RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b5e3e91a-389e-460b-9586-ceefe5a1b764.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-A7RB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0d378225-c108-43ab-8db3-500a38d27efa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 157; copy number 1: 9,835; copy number 2: 42,583; copy number 3: 5,235; copy number 4: 184; copy number 5: 158; copy number 6: 1,490; copy number 10: 25; copy number 11: 78; copy number 15: 33; copy number 16: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-A7RB-01A-11D-A350-01): tumor purity 0.61, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.
- chr7:110,108,031–110,592,204, 3 genes (within-gene range 0–1): AC073114.1, AC073114.2, AC073326.2.
- chr7:110,724,159–110,725,825, 1 gene: AC073326.1.
- chr7:157,739,010–158,031,128, 5 genes: AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1.
- chr16:78,495,926–78,796,362, 5 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1.
- chr18:50,968,019–51,085,045, 2 genes (within-gene range 0–1): AC091551.1, SMAD4.
- chr20:14,884,250–15,619,819, 7 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,819 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:22,725,395–62,275,678, 731 genes, copy number 5–16 (broad region; genes not listed).
- chr8:84,948,585–118,111,826, 477 genes, copy number 6 (broad region; genes not listed).
- chr8:118,620,498–145,066,685, 483 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:30,769,388–30,824,692, 1 gene, copy number 6 (within-gene range 3–6): CRLF3.
- chr17:30,803,654–32,997,877, 99 genes, copy number 6–11 (broad region; genes not listed).
- chr17:33,052,107–33,131,743, 3 genes, copy number 11: AC003687.1, AC008133.2, AC008133.1.
- chr17:34,319,435–35,142,304, 24 genes, copy number 10: CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1.
- chr17:35,164,243–35,167,012, 1 gene, copy number 10: AC022916.4.

Autosomal genes at a single copy (total copy number 1): 7,841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
